Somatic mutation profile of tumor specimen TCGA-53-A4EZ-01A (aliquot TCGA-53-A4EZ-01A-12D-A24P-08) from TCGA case TCGA-53-A4EZ, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.5 years (23,201 days).
Specimen TCGA-53-A4EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cf654d0-0686-4272-8135-1d7f67ed39e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-53-A4EZ-10A (Blood Derived Normal), aliquot TCGA-53-A4EZ-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deeee256-b133-4a0b-ac1f-ce9a4e4929e4

The open-access MAF lists 566 somatic variants for this specimen: 415 protein-altering or splice-affecting, 142 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 353, Silent 142, Nonsense Mutation 28, Splice Site 14, Intron 6, Splice Region 6, Frame Shift Del 6, Frame Shift Ins 6, RNA 3, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0A2 | c.294+1G>A p.X98_splice | Splice Site (SNP) | VAF 35/67 reads (52%) | catalogued as rs80356751, CS080647, COSV100376988; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AUTS2 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 51/133 reads (38%) | catalogued as rs1562957809, COSV61394590; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50262762, COSV50266035; called by muse, mutect2, varscan2
- KNSTRN | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | hotspot (GDC flag); SIFT tolerated, low confidence (1); PolyPhen benign (0.134); catalogued as COSV51105249; called by muse, varscan2
- SCN4A | c.3917G>A p.G1306E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs80338792, CM920619, CM930668, CM930669, COSV101438458; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 42/80 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASS | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100741766, COSV62789138; called by muse, mutect2, varscan2
- ABCA6 | c.4030-2A>C p.X1344_splice | Splice Site (SNP) | VAF 14/23 reads (61%) | catalogued as COSV99446388; called by muse, mutect2
- ABCC6 | c.2738C>G p.P913R | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs765456179, COSV99228667; called by muse, mutect2, varscan2
- ACACA | c.6925G>T p.E2309* | Nonsense Mutation (SNP) | VAF 31/230 reads (13%) | catalogued as rs750543369; called by muse, mutect2, varscan2
- ACSM5 | c.477G>C p.Q159H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs559741756, COSV100088854; called by muse, mutect2, varscan2
- ACVRL1 | c.1442C>A p.T481N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101187897; called by muse, mutect2, varscan2
- ADAM8 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69865337; called by muse, mutect2, varscan2
- ADAMTS14 | c.3334C>A p.P1112T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV100941549; called by muse, mutect2, varscan2
- ADAMTS19 | c.1370T>C p.V457A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV99177502; called by muse, mutect2, varscan2
- ADAMTS20 | c.4615G>T p.G1539W | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV67142637; called by muse, mutect2, varscan2
- ADAMTS20 | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV101239231; called by muse, mutect2, varscan2
- ADAMTS3 | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99710967; called by muse, varscan2
- ADAMTS9 | c.1910G>T p.C637F | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899330; called by muse, mutect2, varscan2
- ADGRB1 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100029593; called by muse, mutect2, varscan2
- ADGRG4 | c.564G>C p.W188C | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99795345, COSV99796015; called by muse, mutect2, varscan2
- AFF3 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100418739; called by muse, mutect2, varscan2
- AGO2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV99595654; called by muse, mutect2, varscan2
- AHNAK2 | c.6580G>T p.G2194W | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370869960, COSV100317350; called by muse, varscan2
- AHNAK2 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs373015857; called by muse, mutect2, varscan2
- AKR1A1 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs148607559, COSV100698714; called by muse, varscan2
- ALG1 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as COSV99275730; called by muse, mutect2, varscan2
- ALMS1 | c.10562A>G p.K3521R | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100042281; called by muse, mutect2, varscan2
- ALX4 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100241049; called by muse, mutect2, varscan2
- ANAPC1 | c.3767G>T p.G1256V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100594684; called by mutect2, varscan2
- ANAPC1 | c.3766G>T p.G1256C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100594685; called by mutect2, varscan2
- ANGPT4 | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV101124720, COSV67921423; called by muse, varscan2
- ANGPT4 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV101124722; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.4220A>T p.H1407L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99783164; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6131C>T p.P2044L | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV99783168; called by muse, mutect2, varscan2
- ANKRD12 | c.4787C>T p.A1596V | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs766459384, COSV50820251; called by muse, mutect2, varscan2
- ANO1 | c.850C>G p.H284D | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100303967; called by muse, mutect2, varscan2
- ANXA13 | c.344C>A p.T115K | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51625888, COSV99146098; called by muse, mutect2, varscan2
- APOB | c.4031A>T p.K1344M | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99265413; called by muse, mutect2, varscan2
- APOBR | c.2638G>C p.V880L (on ENST00000431282; = p.V889L on NM_018690.4) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV100112513; called by muse, mutect2, varscan2
- ARHGAP30 | c.2621G>C p.C874S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs532517541, COSV100920242, COSV63517595; called by muse, mutect2, varscan2
- ARMC6 | c.1132A>T p.T378S (on ENST00000392336; = p.T353S on NM_033415.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV99523018; called by muse, mutect2, varscan2
- ASB4 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100367163; called by muse, mutect2, varscan2
- ASIC3 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99874319; called by muse, mutect2, varscan2
- ASIC3 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99874321; called by muse, mutect2, varscan2
- ASXL3 | c.4667G>T p.C1556F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV99324751; called by muse, mutect2
- ATG2A | c.5809C>T p.Q1937* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as COSV100815522; called by muse, mutect2, varscan2
- ATP2C1 | c.1662A>C p.E554D | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.174); catalogued as COSV100146647; called by muse, mutect2, varscan2
- BAHD1 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101346753; called by muse, mutect2, varscan2
- BEND6 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 90/175 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV100876831; called by muse, mutect2, varscan2
- BMP7 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV67780991; called by muse, mutect2, varscan2
- BSPRY | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as COSV53057499, COSV99444911; called by muse, mutect2, varscan2
- BZW2 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV99334556; called by muse, mutect2, varscan2
- C1orf50 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as COSV100998103; called by muse, mutect2, varscan2
- C2CD2 | c.1883G>A p.R628K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs764104791, COSV100298131; called by muse, mutect2, varscan2
- C2CD2 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100298132, COSV61600089, COSV61600804; called by muse, mutect2, varscan2
- C8B | c.1562G>T p.C521F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100980762; called by muse, mutect2, varscan2
- CACNA1F | c.3270-1G>T p.X1090_splice | Splice Site (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100544733; called by muse, mutect2, varscan2
- CACNG7 | c.423G>T p.S141= | Splice Region (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99711993; called by muse, mutect2, varscan2
- CAMTA1 | c.2392G>T p.G798W | Missense Mutation (SNP) | VAF 113/340 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57901267; called by muse, mutect2, varscan2
- CAPN13 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.156); catalogued as COSV99700180; called by muse, mutect2
- CASKIN2 | c.1488C>G p.N496K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.437); catalogued as COSV100050381; called by muse, mutect2, varscan2
- CASS4 | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV64386420, COSV64386735, COSV64386803; called by muse, mutect2, varscan2
- CCDC65 | c.943C>G p.R315G | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as COSV99872768; called by muse, mutect2
- CCL28 | c.368A>T p.H123L | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100742048; called by muse, mutect2, varscan2
- CCN3 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs758892100, COSV52384067; called by muse, mutect2
- CD300LG | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.375); catalogued as COSV99517389; called by muse, mutect2, varscan2
- CD86 | c.265G>C p.D89H (on ENST00000330540 / NM_175862.5; = p.D83H on NM_006889.4) | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100053945; called by muse, mutect2, varscan2
- CD93 | c.1165T>A p.C389S | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99849188; called by muse, mutect2, varscan2
- CD96 | c.1346C>A p.S449Y (on ENST00000283285 / NM_198196.3; = p.S433Y on NM_005816.5) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as COSV99342827; called by muse, mutect2, varscan2
- CDA | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as COSV100906292; called by muse, varscan2
- CDH20 | c.1530+1G>T p.X510_splice | Splice Site (SNP) | VAF 29/154 reads (19%) | catalogued as COSV99405248; called by muse, mutect2, varscan2
- CDH9 | c.2113C>G p.P705A | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV50449579, COSV99144167; called by muse, mutect2, varscan2
- CDH9 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 72/201 reads (36%) | catalogued as COSV50419019; called by muse, mutect2, varscan2
- CDKN2A | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM119687, COSV58692305; called by muse, mutect2, varscan2
- CELA2A | c.764T>A p.V255D | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100657555; called by muse, mutect2, varscan2
- CELSR2 | c.3972G>T p.E1324D | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV99603726; called by muse, mutect2, varscan2
- CENPF | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV100871667; called by muse, mutect2, varscan2
- CEP126 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV99681008; called by muse, mutect2, varscan2
- CEP126 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV99681012; called by muse, mutect2, varscan2
- CEP350 | c.6760A>G p.K2254E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs759595657, COSV100854595; called by muse, varscan2
- CFAP52 | c.754G>T p.G252* | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | catalogued as COSV100235127; called by muse, mutect2, varscan2
- CHD3 | c.3562G>T p.A1188S | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV100390608, COSV100391172; called by muse, mutect2, varscan2
- CHGB | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV66760259; called by muse, mutect2, varscan2
- CHSY1 | c.431C>G p.P144R | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573862, COSV99573967; called by muse, mutect2, varscan2
- CLCA4 | c.1156T>C p.C386R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99760468; called by muse, mutect2, varscan2
- CNGB1 | c.1739A>T p.E580V | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV99202393; called by muse, mutect2, varscan2
- CNTNAP2 | c.2450G>A p.G817E | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs1275244857; called by muse, mutect2, varscan2
- COL11A1 | c.5158T>A p.W1720R | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616334; called by muse, mutect2, varscan2
- COL3A1 | c.3598G>T p.V1200F | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV100482961; called by muse, mutect2, varscan2
- COL5A1 | c.1719+1G>A p.X573_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100879863; called by muse, mutect2, varscan2
- COL5A3 | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV99318790, COSV99319006; called by muse, mutect2, varscan2
- COL6A6 | c.3536C>T p.A1179V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs770646850, COSV100650205; called by muse, mutect2, varscan2
- CPS1 | c.4475G>T p.R1492M | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV99242873; called by muse, mutect2, varscan2
- CR1 | c.4853G>T p.R1618I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100887569; called by muse, mutect2, varscan2
- CRADD | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV100257486; called by muse, mutect2, varscan2
- CSMD2 | c.9797C>A p.A3266D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99589477; called by muse, mutect2, varscan2
- CSMD3 | c.1646G>T p.G549V (on ENST00000297405 / NM_001363185.1; = p.G445V on NM_052900.3) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99833061; called by muse, mutect2, varscan2
- CYB5D2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100028935; called by muse, mutect2, varscan2
- CYP26C1 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53652490, COSV99605975; called by muse, mutect2
- CYP4F2 | c.1168C>G p.R390G | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99685945; called by muse, mutect2, varscan2
- DACH1 | c.1700A>G p.E567G (on ENST00000619232 / NM_001366712.1; = p.E515G on NM_080759.6) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV100498260; called by muse, mutect2, varscan2
- DGKB | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV99339199; called by muse, mutect2, varscan2
- DNAH10 | c.5552G>T p.G1851V (on ENST00000409039; = p.G1790V on NM_207437.3) | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101292206; called by muse, mutect2, varscan2
- DOCK2 | c.816G>C p.M272I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV99912057; called by muse, mutect2, varscan2
- DOCK5 | c.4900G>C p.E1634Q | Missense Mutation (SNP) | VAF 109/217 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99376816; called by muse, mutect2, varscan2
- DPP3 | c.1453-2A>T p.X485_splice | Splice Site (SNP) | VAF 62/96 reads (65%) | catalogued as COSV100855582; called by muse, mutect2, varscan2
- DPP6 | c.794G>C p.C265S (on ENST00000377770 / NM_001364500.2; = p.C203S on NM_001936.5) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as COSV100125230; called by muse, mutect2, varscan2
- DSCAM | c.1460A>T p.N487I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.399); catalogued as COSV101259970; called by muse, varscan2
- ECHDC3 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV101004540; called by muse, mutect2, varscan2
- ECPAS | c.2806G>T p.V936L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs1209035447, COSV99398122; called by muse, mutect2, varscan2
- EML5 | c.3676G>T p.G1226W | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100715305; called by muse, mutect2, varscan2
- EPB42 | c.1964C>A p.T655K (on ENST00000441366 / NM_001114134.2; = p.T685K on NM_000119.3) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100281609; called by muse, mutect2, varscan2
- EPHA4 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99916398; called by muse, mutect2, varscan2
- EPHA5 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV56628082; called by muse, mutect2, varscan2
- EXOC6 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV53327352; called by muse, mutect2, varscan2
- FAM135B | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV52709678, COSV52718533; called by muse, mutect2, varscan2
- FAM83B | c.2608C>A p.P870T | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as COSV100174429, COSV60921237; called by muse, mutect2, varscan2
- FAT3 | c.2466G>T p.E822D | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV99965572; called by muse, mutect2, varscan2
- FAT4 | c.7873A>G p.I2625V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.111); catalogued as COSV100628456; called by muse, mutect2, varscan2
- FBXO30 | c.37T>C p.C13R | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99395178; called by muse, mutect2, varscan2
- FCHO1 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99406073; called by muse, mutect2, varscan2
- FGB | c.968G>T p.W323L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100122426; called by muse, mutect2, varscan2
- FGF23 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99426276; called by muse, mutect2, varscan2
- FGF23 | c.248T>A p.V83E | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426397; called by muse, mutect2, varscan2
- FLG2 | c.5216G>C p.G1739A | Missense Mutation (SNP) | VAF 82/1319 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.074); catalogued as COSV101165825; called by muse, mutect2
- FMO1 | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100707749; called by muse, mutect2, varscan2
- FNIP1 | c.2687G>T p.C896F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV100330421; called by muse, mutect2, varscan2
- FNIP1 | c.1687G>C p.V563L | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as rs755121685, COSV100330422; called by muse, mutect2, varscan2
- FPR1 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100494057; called by muse, mutect2, varscan2
- FPR1 | c.449G>T p.W150L | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100493949, COSV100494059; called by muse, mutect2, varscan2
- FRY | c.8975G>T p.R2992M | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as COSV66511198; called by muse, mutect2, varscan2
- FSD1 | c.268G>C p.A90P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV99696752; called by muse, mutect2, varscan2
- FSTL5 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs765150532, COSV100054939; called by muse, mutect2, varscan2
- FTSJ1 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.521); catalogued as COSV99191399; called by muse, mutect2, varscan2
- G3BP1 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as COSV100663942; called by muse, mutect2, varscan2
- GABRG3 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100406812; called by muse, mutect2, varscan2
- GBP4 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs186821951, COSV100864374; called by muse, mutect2, varscan2
- GBP6 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as rs866123083, COSV65012502; called by muse, mutect2, varscan2
- GGTLC1 | c.174C>A p.L58= | Splice Region (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99600631; called by muse, mutect2, varscan2
- GJB7 | c.328T>A p.Y110N | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99738300; called by muse, mutect2, varscan2
- GLIS1 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as COSV100389942; called by muse, mutect2
- GMEB1 | c.1135A>T p.R379W | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99603151; called by muse, mutect2, varscan2
- GPC2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 131/335 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.943); catalogued as rs781076566, COSV52783794, COSV52785659; called by muse, mutect2, varscan2
- GPR107 | c.1081A>T p.I361F | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373731941; called by muse, mutect2, varscan2
- GPR149 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as COSV101078325; called by muse, mutect2, varscan2
- GPR17 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs200232871, COSV55756730; called by muse, mutect2, varscan2
- GPR55 | c.338G>C p.C113S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV101235835, COSV67409048; called by muse, mutect2, varscan2
- GRID1 | c.2820C>A p.S940R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV60034842; called by muse, mutect2, varscan2
- GTF3C1 | c.5620G>C p.D1874H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV100649358, COSV62239819, COSV62242723; called by muse, mutect2, varscan2
- HCLS1 | c.1442A>T p.Y481F | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV100100630; called by muse, mutect2, varscan2
- HEATR5B | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as COSV99249188; called by muse, mutect2, varscan2
- HERC1 | c.9929G>A p.R3310Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs765368621, COSV101496536; called by muse, varscan2
- HERC2 | c.8479G>T p.D2827Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99873262; called by muse, mutect2, varscan2
- HERC6 | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99910533; called by muse, mutect2, varscan2
- HOGA1 | c.882G>A p.W294* | Nonsense Mutation (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100167352; called by muse, mutect2, varscan2
- HOXD12 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV101184255; called by muse, mutect2, varscan2
- HOXD9 | c.834C>A p.N278K | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99981942; called by muse, mutect2, varscan2
- HPS3 | c.1299A>G p.I433M | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99937388; called by muse, mutect2, varscan2
- HRNR | c.6350C>A p.S2117Y | Missense Mutation (SNP) | VAF 112/906 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100913421; called by mutect2, varscan2
- HRNR | c.3530C>A p.S1177Y | Missense Mutation (SNP) | VAF 43/611 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV100913424; called by muse, mutect2, varscan2
- HS3ST5 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV100450800, COSV104397372; called by muse, mutect2, varscan2
- HTR1F | c.745A>T p.K249* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV100138068; called by muse, mutect2, varscan2
- HTR3D | c.1018C>A p.P340T (on ENST00000382489 / NM_001163646.2; = p.P165T on NM_182537.3) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100488079; called by muse, mutect2, varscan2
- HTR3D | c.1019C>A p.P340H (on ENST00000382489 / NM_001163646.2; = p.P165H on NM_182537.3) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100488084; called by muse, mutect2, varscan2
- IGSF11 | c.1155G>A p.M385I (on ENST00000393775 / NM_001015887.3; = p.M384I on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1559863810, COSV100677280; called by muse, mutect2, varscan2
- ILDR2 | c.969T>A p.D323E | Missense Mutation (SNP) | VAF 88/150 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99613747; called by muse, mutect2, varscan2
- INHBA | c.907C>A p.H303N | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as COSV99637607; called by muse, mutect2, varscan2
- IQUB | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100227060; called by muse, mutect2, varscan2
- IRS4 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 77/120 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as COSV100929540; called by muse, mutect2, varscan2
- ITGAE | c.2297T>C p.L766P | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.596); catalogued as COSV99560889; called by muse, mutect2, varscan2
- KALRN | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.99); catalogued as COSV99563909; called by muse, mutect2, varscan2
- KANK4 | c.2795C>A p.A932D | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100443184; called by muse, mutect2, varscan2
- KARS1 | c.702G>C p.L234F | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100094012, COSV56693302; called by muse, mutect2, varscan2
- KAT2B | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV99769218; called by muse, mutect2, varscan2
- KCNJ2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54663471, COSV99696346; called by muse, mutect2, varscan2
- KIF19 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.528); catalogued as COSV100739059; called by muse, mutect2, varscan2
- KIFAP3 | c.1799-1G>A p.X600_splice | Splice Site (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100846910, COSV63032278; called by muse, mutect2
- KLHL14 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100808957; called by muse, mutect2, varscan2
- KLK1 | c.565C>A p.H189N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100032713; called by muse, mutect2
- KLK3 | c.586A>C p.M196L | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100385996; called by muse, mutect2
- KRT10 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs563178579, COSV99510042; called by muse, mutect2, varscan2
- KRT25 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100379918; called by muse, mutect2, varscan2
- KRTAP9-8 | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV99565814; called by muse, mutect2, varscan2
- KY | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.022); catalogued as COSV101414981; called by muse, mutect2, varscan2
- LAMA4 | c.4556T>A p.F1519Y (on ENST00000230538 / NM_001105206.3; = p.F1512Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV100038269; called by muse, mutect2, varscan2
- LARP4B | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100295300; called by muse, mutect2, varscan2
- LCE2D | c.119G>C p.C40S | Missense Mutation (SNP) | VAF 84/525 reads (16%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.895); catalogued as COSV100909539; called by muse, mutect2, varscan2
- LGR5 | c.1834G>A p.V612M | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs765873009, COSV57005036; called by muse, mutect2, varscan2
- LIPI | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100753662; called by muse, mutect2, varscan2
- LRATD1 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99707117; called by muse, mutect2, varscan2
- LRP1B | c.10796A>T p.Y3599F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.791); catalogued as COSV101256229; called by muse, mutect2, varscan2
- LRP1B | c.6845C>A p.T2282K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV101256232, COSV67230134; called by muse, mutect2, varscan2
- LRRC15 | c.1625C>G p.A542G | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); catalogued as COSV100752681; called by muse, mutect2, varscan2
- LRRTM4 | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV101297536; called by muse, mutect2, varscan2
- LRRTM4 | c.1016G>T p.C339F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101297537; called by muse, mutect2, varscan2
- LSS | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100710891; called by mutect2, varscan2
- MACF1 | c.6295G>T p.A2099S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV99243916; called by muse, mutect2, varscan2
- MED13 | c.3011C>T p.P1004L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101181014; called by muse, mutect2, varscan2
- MEGF10 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV99174911; called by muse, mutect2, varscan2
- MGAT3 | c.1379G>T p.R460L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100361853; called by muse, mutect2, varscan2
- MINAR1 | c.359A>T p.E120V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV100548868; called by muse, mutect2, varscan2
- MMADHC | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100307169; called by muse, mutect2, varscan2
- MMRN1 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99307039; called by muse, mutect2, varscan2
- MOCOS | c.682A>T p.S228C | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99733229; called by muse, mutect2, varscan2
- MOS | c.926C>A p.P309H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.669); catalogued as COSV100322818; called by muse, mutect2, varscan2
- MPEG1 | c.890C>A p.T297N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99915354; called by muse, mutect2, varscan2
- MRPS9 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150040776; called by muse, mutect2, varscan2
- MS4A12 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); catalogued as rs776245356, COSV50014983; called by muse, mutect2, varscan2
- MTOR | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.112); catalogued as COSV100816119; called by muse, mutect2, varscan2
- MUC16 | c.15807C>G p.I5269M | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV101199724; called by muse, mutect2, varscan2
- MUC17 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 215/767 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.134); catalogued as COSV60303278; called by muse, mutect2, varscan2
- MYH2 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV55438538, COSV99820030; called by muse, mutect2, varscan2
- MYH3 | c.5059G>T p.E1687* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as COSV99878151; called by muse, mutect2, varscan2
- MYH8 | c.3091G>C p.E1031Q | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as rs1453653455, COSV101238394; called by muse, mutect2, varscan2
- MYPN | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100589906; called by muse, mutect2, varscan2
- MYPN | c.3379G>C p.G1127R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752302519, COSV100589908; called by muse, mutect2, varscan2
- NAGK | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99730605; called by muse, mutect2, varscan2
- NAV2 | c.5178G>T p.Q1726H (on ENST00000396087 / NM_001244963.2; = p.Q1670H on NM_145117.5) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100216788; called by muse, mutect2
- NAV3 | c.5613C>A p.S1871R (on ENST00000397909 / NM_001024383.2; = p.S1849R on NM_014903.6) | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99890306; called by muse, mutect2, varscan2
- NBAS | c.6451G>C p.E2151Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.355); catalogued as COSV99869259; called by muse, mutect2, varscan2
- NCF1 | c.575-1G>A p.X192_splice | Splice Site (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99194271; called by muse, mutect2, varscan2
- NCL | c.1410T>A p.N470K | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV100502337; called by muse, mutect2, varscan2
- NDRG2 | c.718C>T p.R240C (on ENST00000298687 / NM_001354570.1; = p.R226C on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs777809812, COSV100068959; called by muse, mutect2, varscan2
- NID2 | c.2158A>T p.T720S | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV53497221, COSV99356434; called by muse, mutect2, varscan2
- NIPAL4 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV99977028; called by muse, mutect2, varscan2
- NIPBL | c.5428-1G>T p.X1810_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99240382; called by muse, mutect2, varscan2
- NOS1 | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV100500508; called by muse, mutect2, varscan2
- NOX5 | c.1168C>A p.R390S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52992347, COSV99533788; called by muse, mutect2, varscan2
- NPAP1 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.047); catalogued as COSV100275292; called by muse, mutect2, varscan2
- NPAP1 | c.2344C>A p.Q782K | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.133); catalogued as COSV100275293; called by muse, mutect2, varscan2
- NPY2R | c.451T>C p.C151R | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100279618, COSV100279667; called by muse, mutect2, varscan2
- NR3C1 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99196278; called by muse, mutect2, varscan2
- NT5DC1 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100126375, COSV60308607; called by muse, mutect2, varscan2
- NTRK2 | c.2338C>A p.Q780K (on ENST00000323115 / NM_001369534.1; = p.Q796K on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99455025; called by muse, mutect2, varscan2
- NTRK3 | c.2262G>T p.W754C (on ENST00000360948 / NM_001012338.2; = p.W740C on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100712707, COSV62300211; called by muse, mutect2, varscan2
- NUTM1 | c.2599C>A p.L867I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV100148985; called by muse, mutect2, varscan2
- ODR4 | c.1085T>C p.F362S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99834307; called by muse, mutect2, varscan2
- OPA1 | c.1605C>G p.S535R (on ENST00000361510 / NM_130837.3; = p.S480R on NM_015560.3) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV62479707; called by muse, mutect2, varscan2
- OR1L8 | c.829G>T p.V277F | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); catalogued as COSV100508529; called by muse, mutect2, varscan2
- OR1S1 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.903); catalogued as COSV100515371; called by muse, mutect2, varscan2
- OR2A5 | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 118/302 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV101278740; called by muse, mutect2, varscan2
- OR2AG1 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100264858, COSV56625856; called by muse, mutect2, varscan2
- OR2T33 | c.671T>G p.L224R | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100531870; called by muse, mutect2, varscan2
- OR4C16 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100114041; called by muse, mutect2, varscan2
- OR4C6 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 60/158 reads (38%) | catalogued as COSV100051592; called by muse, mutect2, varscan2
- OR4F5 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 69/455 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100633184; called by muse, mutect2, varscan2
- OR4K1 | c.916G>T p.V306L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1207349568, COSV99578950; called by muse, mutect2
- OR5AS1 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs753231648, COSV100546255; called by muse, mutect2, varscan2
- OR5D18 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100450667; called by muse, mutect2, varscan2
- OR5L1 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100450035, COSV61734120; called by muse, mutect2, varscan2
- OR5W2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV100747611; called by muse, mutect2, varscan2
- OVCH2 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101491887; called by muse, mutect2, varscan2
- P2RX5 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV99835774; called by muse, mutect2, varscan2
- PACRG | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100433891; called by muse, mutect2, varscan2
- PARP15 | c.1892G>C p.G631A (on ENST00000464300 / NM_001113523.3; = p.G397A on NM_152615.2) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100117068; called by muse, mutect2, varscan2
- PCDHA2 | c.1613G>T p.R538L | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as COSV100973816, COSV100974180; called by muse, mutect2, varscan2
- PCDHA9 | c.2101A>G p.I701V | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as rs1229783262, COSV100969467; called by muse, mutect2, varscan2
- PCDHB10 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); catalogued as COSV53379857, COSV99504202; called by muse, mutect2, varscan2
- PCDHB8 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV50754681; called by muse, mutect2, varscan2
- PCDHGA5 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); catalogued as rs1235589231, COSV99537250; called by muse, varscan2
- PCDHGB6 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780485949, COSV99537253; called by muse, mutect2, varscan2
- PCLO | c.11191G>T p.E3731* | Nonsense Mutation (SNP) | VAF 22/115 reads (19%) | catalogued as COSV100431943; called by muse, mutect2, varscan2
- PCSK7 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100309338; called by muse, mutect2, varscan2
- PDCD1LG2 | c.766+1G>A p.X256_splice | Splice Site (SNP) | VAF 33/98 reads (34%) | catalogued as rs1455119244, COSV101173091; called by muse, mutect2, varscan2
- PDHA2 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as COSV99756849; called by muse, mutect2, varscan2
- PEAK1 | c.78G>T p.L26F | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV100432930; called by muse, mutect2, varscan2
- PEX5L | c.1070del p.P357Lfs*12 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | catalogued as COSV55858297; called by mutect2, pindel, varscan2
- PFKFB3 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 18/181 reads (10%) | PolyPhen possibly damaging (0.895); catalogued as COSV100431997; called by muse, mutect2
- PGAP1 | c.2489G>T p.S830I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100698173; called by muse, mutect2, varscan2
- PHLPP1 | c.4114G>T p.G1372C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99408118; called by muse, mutect2
- PIF1 | c.1721C>G p.A574G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV99164965; called by muse, mutect2, varscan2
- PIF1 | c.1335T>A p.G445= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99164969; called by mutect2, varscan2
- PIK3R5 | c.290C>A p.P97Q | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99353262; called by muse, mutect2, varscan2
- PKHD1 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV100582911, COSV61880933; called by muse, mutect2, varscan2
- PLCL1 | c.1070T>G p.I357R | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101406898; called by muse, mutect2, varscan2
- PLIN5 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.423); catalogued as rs373982855, COSV101113497; called by muse, mutect2, varscan2
- PLPPR4 | c.298G>T p.G100* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV100927053; called by muse, mutect2, varscan2
- POTEA | c.1219-1G>C p.X407_splice (on ENST00000519951 / NM_001005365.2; = p.X361_splice on NM_001002920.1) | Splice Site (SNP) | VAF 92/177 reads (52%) | catalogued as rs1203683912; called by muse, mutect2, varscan2
- POTEE | c.582C>A p.D194E | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100387792; called by mutect2, varscan2
- PPEF2 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV99714501; called by muse, mutect2, varscan2
- PPT1 | c.415G>C p.G139R (on ENST00000433473; = p.G140R on NM_000310.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100858381, COSV100858431, COSV65656142; called by muse, mutect2, varscan2
- PRDM10 | c.763-1G>T p.X255_splice | Splice Site (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100456744; called by muse, mutect2, varscan2
- PRDM2 | c.1223A>T p.H408L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99341537; called by muse, mutect2, varscan2
- PRDM9 | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99690369, COSV99690464; called by muse, mutect2, varscan2
- PRPF3 | c.1702T>C p.Y568H | Missense Mutation (SNP) | VAF 103/657 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV100254749; called by muse, mutect2, varscan2
- PSG2 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 175/612 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.182); catalogued as COSV100283503, COSV61545608; called by muse, mutect2, varscan2
- PTPRC | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.076); catalogued as rs760015972, COSV100722586; called by muse, mutect2, varscan2
- RABGAP1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100438555; called by muse, mutect2, varscan2
- RAD51AP2 | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV101208333; called by muse, mutect2, varscan2
- RAD51AP2 | c.1669A>T p.T557S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV101208334; called by muse, mutect2, varscan2
- RALGDS | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100924423; called by muse, mutect2, varscan2
- RASA3 | c.603+1G>T p.X201_splice | Splice Site (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100480457; called by muse, mutect2, varscan2
- RASGEF1A | c.1149C>G p.N383K | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100988659; called by muse, mutect2, varscan2
- RIMS2 | c.4317G>A p.M1439I (on ENST00000666250 / NM_001348490.2; = p.M1010I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.513); catalogued as rs752817349, COSV51706399; called by muse, mutect2
- RING1 | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.057); catalogued as rs113695132, COSV100761768; called by muse, mutect2, varscan2
- RNF112 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV101465409; called by muse, mutect2, varscan2
- RNF17 | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99693054; called by muse, mutect2, varscan2
- RNF19B | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99331422; called by muse, mutect2, varscan2
- RPIA | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99376117; called by muse, mutect2
- RPRD2 | c.404A>G p.E135G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as COSV100954716; called by muse, mutect2
- RTP5 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.482); catalogued as COSV100574718; called by muse, mutect2
- S100A5 | c.229A>C p.T77P | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100785915; called by muse, mutect2, varscan2
- SAFB2 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV99385691; called by muse, varscan2
- SAFB2 | c.1640A>T p.Q547L | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99385693; called by muse, mutect2, varscan2
- SAV1 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV61204716; called by muse, mutect2, varscan2
- SEC23B | c.568del p.R190Efs*6 | Frame Shift Del (DEL) | VAF 44/170 reads (26%) | catalogued as rs1412390184; called by mutect2, pindel, varscan2
- SEL1L2 | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53151472; called by muse, mutect2, varscan2
- SERPINA12 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100369664, COSV100369775, COSV100369852; called by muse, mutect2, varscan2
- SETBP1 | c.3191G>T p.G1064V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99953107; called by muse, mutect2, varscan2
- SF3B1 | c.3538A>C p.R1180= | Splice Region (SNP) | VAF 35/153 reads (23%) | catalogued as COSV100134596, COSV59219985; called by muse, mutect2, varscan2
- SH3BP4 | c.2769G>T p.K923N | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV100749139; called by muse, mutect2, varscan2
- SIK3 | c.2732G>T p.S911I (on ENST00000445177 / NM_001366686.2; = p.S869I on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV99407916; called by muse, mutect2, varscan2
- SLC25A36 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV100148956, COSV100149045; called by muse, mutect2, varscan2
- SLC26A11 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100755367; called by muse, mutect2, varscan2
- SLC28A2 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV100754692; called by muse, mutect2, varscan2
- SLC2A4 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV99142707; called by muse, mutect2, varscan2
- SLC39A11 | c.638G>A p.G213E (on ENST00000542342 / NM_001159770.2; = p.G206E on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99722969; called by muse, mutect2, varscan2
- SLC6A3 | c.775G>T p.V259L | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99547801, COSV99548234; called by muse, mutect2, varscan2
- SLITRK1 | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1029114209, COSV100999932; called by muse, mutect2, varscan2
- SLITRK2 | c.2372G>T p.R791L | Missense Mutation (SNP) | VAF 73/121 reads (60%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV59425873, COSV59427820; called by muse, mutect2, varscan2
- SLITRK6 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV101233225; called by muse, mutect2, varscan2
- SNIP1 | c.1134A>T p.E378D | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as COSV99953099; called by muse, mutect2, varscan2
- SNTG2 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs1226979441, COSV100422318; called by muse, mutect2, varscan2
- SNX4 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV99304920; called by muse, mutect2, varscan2
- SPAG7 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99236434; called by muse, mutect2, varscan2
- SRSF5 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as rs141668513, COSV99384315; called by muse, mutect2, varscan2
- SULF2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63420414; called by muse, mutect2, varscan2
- SVOPL | c.515A>G p.Y172C (on ENST00000419765; = p.Y20C on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.601); catalogued as rs1563123739, COSV99939311; called by muse, mutect2, varscan2
- SYT4 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs768611116, COSV54901826, COSV99673755; called by muse, mutect2, varscan2
- TACR1 | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100537873; called by muse, mutect2, varscan2
- TAF1L | c.5436G>A p.M1812I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as COSV99644573; called by muse, varscan2
- TAF1L | c.5368C>T p.Q1790* | Nonsense Mutation (SNP) | VAF 50/118 reads (42%) | catalogued as COSV99644576; called by muse, varscan2
- TBC1D9 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101464330; called by muse, mutect2, varscan2
- TCEAL5 | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 96/163 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV101013125; called by muse, mutect2, varscan2
- TCF4 | c.1277A>G p.H426R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100610149; called by muse, mutect2, varscan2
- TECRL | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1459396928, COSV101168864; called by muse, mutect2, varscan2
- TENM3 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.137); catalogued as COSV69304408; called by muse, mutect2, varscan2
- TEX15 | c.51G>C p.W17C (on ENST00000256246; = p.W400C on NM_001350162.2) | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV99821276; called by muse, mutect2, varscan2
- TMEM132D | c.3023C>A p.S1008Y | Missense Mutation (SNP) | VAF 85/174 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as COSV101242795; called by muse, mutect2, varscan2
- TMEM176B | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100423539, COSV58440482; called by muse, mutect2
- TMPRSS3 | c.858G>T p.L286F | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); catalogued as COSV52309257, COSV99367990; called by muse, mutect2, varscan2
- TNR | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as rs770736403, COSV54874085; called by muse, mutect2, varscan2
- TP53BP1 | c.1524G>T p.L508F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.476); catalogued as COSV99780427; called by muse, mutect2, varscan2
- TP63 | c.765G>T p.E255D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99286762; called by muse, mutect2, varscan2
- TRAIP | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100513180; called by muse, mutect2, varscan2
- TRAK1 | c.1965G>A p.A655= | Splice Region (SNP) | VAF 57/162 reads (35%) | catalogued as rs545460609, COSV59638775; called by muse, mutect2, varscan2
- TRHDE | c.2281C>A p.L761I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV53866784, COSV99670537; called by muse, mutect2, varscan2
- TRIM42 | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99648325; called by muse, mutect2, varscan2
- TRIO | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710293; called by muse, mutect2, varscan2
- TRPC4 | c.2029T>A p.L677M | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV100156719, COSV59010317; called by muse, mutect2, varscan2
- TRPM4 | c.508G>C p.V170L | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99419674; called by muse, varscan2
- TRRAP | c.3628C>G p.L1210V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV100722425; called by muse, mutect2, varscan2
- TSPOAP1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.674); catalogued as COSV99270952; called by muse, mutect2, varscan2
- TTC32 | c.89T>A p.L30Q | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100367806; called by muse, mutect2, varscan2
- TTLL13P | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100296539; called by muse, mutect2, varscan2
- TTLL3 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 58/139 reads (42%) | catalogued as COSV100047478; called by muse, mutect2, varscan2
- TTN | c.84070A>G p.I28024V (on ENST00000591111; = p.I20600V on NM_003319.4) | Missense Mutation (SNP) | VAF 77/231 reads (33%) | PolyPhen benign (0.006); catalogued as COSV100610596; called by muse, mutect2, varscan2
- TTN | c.82073A>T p.H27358L (on ENST00000591111; = p.H19934L on NM_003319.4) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | PolyPhen benign (0.067); catalogued as COSV100610597; called by muse, mutect2, varscan2
- TTN | c.46759G>T p.A15587S (on ENST00000591111; = p.A8163S on NM_003319.4) | Missense Mutation (SNP) | VAF 111/349 reads (32%) | PolyPhen probably damaging (0.998); catalogued as COSV100610599; called by muse, mutect2, varscan2
- TTN | c.39126T>A p.S13042R (on ENST00000591111; = p.S5618R on NM_003319.4) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | PolyPhen probably damaging (0.997); catalogued as COSV100610600; called by muse, mutect2, varscan2
- TTN | c.16028T>G p.V5343G (on ENST00000591111; = p.V4416G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/153 reads (31%) | PolyPhen probably damaging (0.974); catalogued as COSV100592261, COSV100610617; called by muse, mutect2, varscan2
- UBASH3A | c.1007C>A p.T336K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99369544; called by muse, mutect2, varscan2
- UNC13C | c.1114G>C p.A372P | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV52841437, COSV99516562; called by muse, mutect2, varscan2
- UNK | c.2417A>T p.H806L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99256596; called by muse, mutect2, varscan2
- USP20 | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.207); catalogued as COSV100204276; called by muse, mutect2, varscan2
- USP29 | c.2627C>T p.S876F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99518049; called by muse, mutect2, varscan2
- USP45 | c.1684C>G p.L562V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.268); catalogued as COSV100569633; called by muse, mutect2, varscan2
- VCAN | c.10013G>A p.R3338Q | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754880024, COSV54098444; called by muse, mutect2, varscan2
- VGF | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV99973001; called by muse, mutect2, varscan2
- VNN1 | c.1203G>T p.L401F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100907711; called by muse, mutect2, varscan2
- VSIG8 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100928791; called by muse, mutect2, varscan2
- WDR1 | c.1499A>T p.D500V (on ENST00000382452; = p.D360V on NM_005112.5) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101221112; called by muse, mutect2, varscan2
- WDR72 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100854413; called by muse, mutect2, varscan2
- WNT8B | c.164del p.K55Sfs*46 | Frame Shift Del (DEL) | VAF 30/85 reads (35%) | catalogued as rs745389332; called by mutect2, pindel, varscan2
- WRN | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as rs758055295, COSV99988934; called by muse, mutect2, varscan2
- XDH | c.1630G>T p.A544S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV101052185; called by muse, mutect2
- XIRP2 | c.8222C>G p.S2741* (on ENST00000628543; = p.S2916* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 17/173 reads (10%) | catalogued as COSV99742373; called by muse, mutect2, varscan2
- XIRP2 | c.9190A>G p.T3064A (on ENST00000628543; = p.T3239A on NM_152381.6) | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.182); catalogued as rs774555613, COSV99742375; called by muse, mutect2, varscan2
- YIPF7 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV100274486; called by muse, mutect2
- YWHAE | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV51984613; called by muse, mutect2, varscan2
- ZBTB7B | c.1108G>C p.G370R (on ENST00000292176; = p.G404R on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99421132; called by muse, mutect2, varscan2
- ZFHX4 | c.7280C>T p.P2427L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs760554402, COSV99262250; called by muse, varscan2
- ZIC4 | c.357C>G p.Y119* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as COSV101267951; called by muse, mutect2, varscan2
- ZMYND8 | c.1070T>G p.F357C (on ENST00000311275 / NM_001363741.2; = p.F377C on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99520286; called by muse, mutect2, varscan2
- ZNF254 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 40/134 reads (30%) | catalogued as COSV100741606; called by muse, mutect2, varscan2
- ZNF256 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 27/162 reads (17%) | catalogued as COSV99990798, COSV99991038; called by muse, mutect2, varscan2
- ZNF267 | c.2161T>G p.C721G | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100339732; called by muse, mutect2, varscan2
- ZNF350 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99702505; called by muse, mutect2, varscan2
- ZNF518A | c.912G>T p.M304I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100283493; called by muse, mutect2
- ZNF518A | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100283494; called by muse, mutect2
- ZNF773 | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as rs753394618, COSV99989261; called by muse, mutect2, varscan2
- ZNF808 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | catalogued as COSV100707909; called by muse, mutect2, varscan2
- ZNF813 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 63/210 reads (30%) | catalogued as COSV101124681, COSV101124835; called by muse, mutect2, varscan2
- ZNF831 | c.4279C>A p.L1427M | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV100925989; called by muse, mutect2, varscan2
- ZP4 | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.212); catalogued as COSV100850665; called by muse, mutect2, varscan2
- ZSWIM2 | c.249G>T p.L83F | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99720167; called by muse, mutect2, varscan2
- AC126283.2 | c.1518dup p.E507Rfs*8 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- AGL | c.3920C>T p.P1307L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATXN2L | c.2965_2970del p.M989_L990del | In Frame Del (DEL) | VAF 36/104 reads (35%) | called by mutect2, pindel, varscan2
- FCGBP | c.3301C>T p.Q1101* | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | called by muse, mutect2, varscan2
- GTF2H2B | n.860G>T | Splice Region (SNP) | VAF 40/94 reads (43%) | called by mutect2, varscan2
- KIRREL2 | c.346del p.Q116Nfs*29 | Frame Shift Del (DEL) | VAF 33/132 reads (25%) | called by mutect2, pindel, varscan2
- LRTM2 | c.325dup p.R109Pfs*12 | Frame Shift Ins (INS) | VAF 36/135 reads (27%) | called by mutect2, pindel, varscan2
- OR10H1 | c.944dup p.N315Kfs*22 | Frame Shift Ins (INS) | VAF 30/78 reads (38%) | called by mutect2, varscan2
- PCDH15 | c.4837del p.E1613Nfs*207 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, varscan2
- PDE9A | c.70-1G>C p.X24_splice | Splice Site (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2
- POTEA | c.967C>A p.Q323K (on ENST00000519951 / NM_001005365.2; = p.Q277K on NM_001002920.1) | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRAMEF7 | c.1280G>C p.G427A | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.406); called by muse, mutect2
- PRDM9 | c.1208_1209del p.L403Qfs*45 | Frame Shift Del (DEL) | VAF 37/161 reads (23%) | called by pindel, varscan2
- SLCO1C1 | c.1529dup p.N510Kfs*21 | Frame Shift Ins (INS) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- SNTG1 | c.228dup p.E77Rfs*3 | Frame Shift Ins (INS) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- SOHLH1 | c.508dup p.L170Pfs*35 | Frame Shift Ins (INS) | VAF 26/78 reads (33%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 112/289 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ABCC8 | c.4639C>T p.L1547= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100217192; called by muse, mutect2, varscan2
- ACHE | c.933C>G p.V311= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV53820592, COSV99574044; called by muse, mutect2, varscan2
- ACO2 | c.1692C>A p.R564= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV99347334; called by muse, mutect2, varscan2
- ACVRL1 | c.1443C>A p.T481= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101187797, COSV101187804; called by muse, mutect2, varscan2
- ADCY8 | c.3385C>A p.R1129= | Silent (SNP) | VAF 140/270 reads (52%) | catalogued as COSV53928979, COSV99652052; called by muse, mutect2, varscan2
- ALMS1 | c.8679C>T p.A2893= | Silent (SNP) | VAF 72/316 reads (23%) | catalogued as COSV100042279; called by muse, varscan2
- ANKS1B | c.504G>T p.A168= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100245288; called by muse, mutect2, varscan2
- APBA2 | c.1605C>T p.P535= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs770411452, COSV101258153; called by muse, mutect2, varscan2
- BCAM | c.792G>T p.T264= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as COSV99538679; called by muse, mutect2, varscan2
- BCHE | c.813G>T p.T271= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as rs1398040946, COSV52257855; called by muse, mutect2, varscan2
- BFSP2 | c.528G>C p.L176= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100183728; called by muse, mutect2, varscan2
- BRSK1 | c.1836A>G p.L612= | Silent (SNP) | VAF 83/338 reads (25%) | catalogued as COSV100474008; called by muse, mutect2, varscan2
- C4BPA | c.1656C>A p.G552= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV100891203; called by muse, mutect2, varscan2
- CAMK2B | c.1449A>T p.L483= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1447486278, COSV99323003; called by muse, mutect2, varscan2
- CAMKV | c.255G>A p.L85= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99615458; called by muse, mutect2, varscan2
- CCDC65 | c.1092G>T p.L364= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99872770; called by muse, mutect2
- CCKBR | c.1158C>T p.N386= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as rs141279039, COSV100582916; called by muse, mutect2, varscan2
- CDH20 | c.2061G>C p.R687= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV53017236, COSV99405249; called by muse, mutect2, varscan2
- CEACAM20 | c.162C>T p.T54= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as COSV100386867; called by muse, mutect2, varscan2
- CEL | c.1410C>T p.F470= (on ENST00000673714; = p.F467= on NM_001807.6) | Silent (SNP) | VAF 31/190 reads (16%) | catalogued as rs749103720, COSV60826385; called by muse, mutect2, varscan2
- CENPF | c.2955C>T p.S985= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs751726847, COSV100871668; called by muse, mutect2, varscan2
- CES2 | c.780C>T p.P260= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs770964350, COSV100399214, COSV100399420; called by muse, mutect2, varscan2
- CFAP20DC | c.897G>T p.P299= (on ENST00000482387 / NM_001351530.2; = p.P174= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 43/77 reads (56%) | catalogued as rs570968646, COSV99918621; called by muse, mutect2, varscan2
- CFAP91 | c.225C>T p.T75= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV99847081; called by muse, mutect2, varscan2
- CHRNA5 | c.889C>T p.L297= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100213891; called by muse, mutect2, varscan2
- CLCA1 | c.2604A>G p.P868= | Silent (SNP) | VAF 49/191 reads (26%) | catalogued as COSV99322299; called by muse, mutect2, varscan2
- CLEC18B | c.672C>A p.L224= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs1277222527, COSV100375908; called by muse, mutect2, varscan2
- CLIP2 | c.1068C>A p.A356= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99791512; called by muse, mutect2, varscan2
- COL20A1 | c.3132G>T p.R1044= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV100490481; called by muse, mutect2, varscan2
- COL9A3 | c.441C>T p.P147= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs41306378, COSV100673381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORO2B | c.594G>T p.T198= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99963212; called by muse, mutect2, varscan2
- CPSF2 | c.891C>T p.D297= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV100102791; called by muse, mutect2, varscan2
- CRADD | c.549G>C p.G183= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV100257583; called by muse, mutect2, varscan2
- CSMD2 | c.525C>A p.A175= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV53912990, COSV99589479; called by muse, mutect2, varscan2
- CYP3A7 | c.207A>G p.R69= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs1161824958, COSV100312645; called by muse, mutect2, varscan2
- DDX24 | c.1509G>T p.T503= | Silent (SNP) | VAF 56/218 reads (26%) | catalogued as rs775552312, COSV100427913, COSV58213269; called by muse, mutect2, varscan2
- DPP6 | c.336C>A p.T112= (on ENST00000377770 / NM_001364500.2; = p.T50= on NM_001936.5) | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV100125228; called by muse, mutect2, varscan2
- DSCAM | c.744G>C p.A248= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV101259972; called by muse, mutect2, varscan2
- DSCAML1 | c.2106C>G p.G702= (on ENST00000321322; = p.G642= on NM_020693.4) | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV100355806; called by muse, mutect2, varscan2
- DUS2 | c.90G>A p.L30= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV100732495; called by muse, mutect2, varscan2
- EMP1 | c.473A>G p.*158= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs755548621, COSV99916930; called by muse, mutect2, varscan2
- ENDOD1 | c.1215G>T p.V405= | Silent (SNP) | VAF 46/163 reads (28%) | catalogued as COSV99566531; called by muse, mutect2, varscan2
- EPB42 | c.225C>A p.T75= (on ENST00000441366 / NM_001114134.2; = p.T105= on NM_000119.3) | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV55748959; called by muse, mutect2, varscan2
- ERN2 | c.111A>T p.P37= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV99891419; called by muse, mutect2, varscan2
- EYA1 | c.1710C>A p.P570= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100379296; called by muse, mutect2, varscan2
- FAM135B | c.2625C>A p.T875= | Silent (SNP) | VAF 87/180 reads (48%) | catalogued as rs777853336, COSV99423392; called by muse, mutect2, varscan2
- FAT3 | c.8826G>T p.V2942= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV99965575; called by muse, mutect2, varscan2
- FECH | c.342C>T p.R114= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV100023550; called by muse, mutect2, varscan2
- FMOD | c.609G>T p.T203= | Silent (SNP) | VAF 129/286 reads (45%) | catalogued as COSV100724538; called by muse, mutect2, varscan2
- FPR2 | c.573G>T p.L191= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as COSV100389267; called by muse, mutect2, varscan2
- GABRA6 | c.852C>A p.T284= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV50889138; called by muse, mutect2, varscan2
- GAD2 | c.291G>T p.L97= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV99393174; called by muse, mutect2, varscan2
- GLI3 | c.3852C>A p.T1284= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV101229842; called by muse, mutect2, varscan2
- GPR150 | c.201G>C p.L67= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs746984265, COSV101187404; called by muse, varscan2
- GRIA3 | c.982C>A p.R328= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV99989977; called by muse, mutect2, varscan2
- GRID1 | c.2821C>A p.R941= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100023814, COSV60049045; called by muse, mutect2, varscan2
- GRM1 | c.1785A>T p.I595= | Silent (SNP) | VAF 95/211 reads (45%) | catalogued as COSV99265939, COSV99269528; called by muse, mutect2, varscan2
- HOXA9 | c.42G>A p.S14= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs367823279; called by muse, mutect2, varscan2
- IGKC | c.82C>T p.L28= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- IGSF1 | c.3888A>C p.T1296= | Silent (SNP) | VAF 87/157 reads (55%) | catalogued as COSV100812060; called by muse, mutect2, varscan2
- INTS2 | c.2235G>T p.L745= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV52152645, COSV99248076; called by muse, mutect2, varscan2
- KCNMB2 | c.570C>A p.L190= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV100843929, COSV64200803; called by muse, mutect2, varscan2
- KIAA1549L | c.327T>C p.F109= (on ENST00000321505; = p.F406= on NM_012194.3) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99683386; called by muse, mutect2, varscan2
- KIAA1549L | c.921C>A p.T307= (on ENST00000321505; = p.T604= on NM_012194.3) | Silent (SNP) | VAF 53/200 reads (27%) | catalogued as COSV55771470, COSV99683389; called by muse, mutect2, varscan2
- KLF10 | c.312T>C p.S104= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as rs767017322, COSV99574732; called by muse, mutect2, varscan2
- KMT5C | c.1254C>T p.A418= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV99726172; called by muse, mutect2, varscan2
- KRT84 | c.507C>T p.I169= | Silent (SNP) | VAF 66/325 reads (20%) | catalogued as COSV99230843; called by muse, mutect2, varscan2
- KRTAP21-1 | c.202C>A p.R68= | Silent (SNP) | VAF 55/208 reads (26%) | catalogued as COSV100624930, COSV58646813; called by muse, mutect2, varscan2
- LAIR2 | c.222G>T p.V74= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as COSV100003261; called by muse, mutect2, varscan2
- LGI4 | c.768C>A p.R256= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100032495; called by muse, mutect2, varscan2
- LGR5 | c.1428T>A p.A476= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as COSV99877870; called by muse, mutect2, varscan2
- LUZP2 | c.705G>C p.R235= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV100419771; called by muse, mutect2, varscan2
- MAGEA12 | c.297T>A p.P99= | Silent (SNP) | VAF 83/133 reads (62%) | catalogued as COSV100756905; called by muse, mutect2, varscan2
- MBD5 | c.3213G>T p.V1071= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV101290074; called by muse, mutect2, varscan2
- MKRN1 | c.468T>C p.F156= | Silent (SNP) | VAF 47/202 reads (23%) | catalogued as COSV99751617; called by muse, mutect2, varscan2
- MLLT10 | c.2292G>A p.L764= (on ENST00000307729 / NM_001195626.3; = p.L780= on NM_004641.3) | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100308045; called by muse, mutect2, varscan2
- MMP16 | c.60G>T p.V20= | Silent (SNP) | VAF 34/186 reads (18%) | catalogued as COSV99687913; called by muse, mutect2, varscan2
- MSLNL | c.645C>A p.A215= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99558248; called by muse, mutect2
- MSMB | c.105C>A p.T35= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- MUC16 | c.16536C>A p.P5512= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV67445491; called by muse, mutect2
- MUC17 | c.8946T>C p.P2982= | Silent (SNP) | VAF 321/805 reads (40%) | catalogued as COSV100073011; called by muse, mutect2, varscan2
- MYH6 | c.360C>A p.L120= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as COSV100676538; called by muse, mutect2, varscan2
- MYO7B | c.1470C>A p.T490= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV101268131, COSV67345495; called by muse, mutect2, varscan2
- NAT16 | c.282G>A p.T94= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs756753482, COSV100296260; called by muse, mutect2, varscan2
- NBN | c.1779A>T p.P593= | Silent (SNP) | VAF 139/282 reads (49%) | catalogued as COSV99619400; called by muse, mutect2, varscan2
- NCR1 | c.327C>T p.P109= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV99400903; called by muse, mutect2, varscan2
- NFATC2 | c.2670G>T p.A890= | Silent (SNP) | VAF 73/165 reads (44%) | catalogued as COSV101044043, COSV65353560; called by muse, mutect2, varscan2
- NFKBIA | c.474C>T p.A158= | Silent (SNP) | VAF 58/177 reads (33%) | catalogued as rs1490475945, COSV99395107; called by muse, mutect2, varscan2
- NOL6 | c.2454G>A p.L818= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs753741911, COSV99954700; called by muse, mutect2, varscan2
- NPAS2 | c.1740G>T p.G580= | Silent (SNP) | VAF 64/217 reads (29%) | catalogued as COSV100176140; called by muse, mutect2, varscan2
- NTRK2 | c.2148C>A p.P716= (on ENST00000323115 / NM_001369534.1; = p.P732= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as COSV99455022; called by muse, mutect2, varscan2
- NUTM1 | c.450C>A p.V150= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100412280; called by muse, mutect2, varscan2
- OR10AG1 | c.255G>A p.L85= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs1479218233, COSV100400059; called by muse, mutect2, varscan2
- OR2T12 | c.483C>A p.T161= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV100527736; called by muse, mutect2, varscan2
- OSBPL11 | c.1122G>A p.L374= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV99954141; called by muse, mutect2, varscan2
- OTUD7A | c.1638G>T p.V546= (on ENST00000307050 / NM_001382637.1; = p.V539= on NM_130901.3) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100192403; called by muse, mutect2, varscan2
- OVCH1 | c.837C>A p.G279= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs759329738, COSV100548539; called by muse, varscan2
- PALLD | c.1137A>G p.R379= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV99824630; called by muse, mutect2, varscan2
- PAX8 | c.328C>A p.R110= | Silent (SNP) | VAF 115/418 reads (28%) | catalogued as COSV99639455; called by muse, mutect2, varscan2
- PCDH11X | c.3078T>A p.S1026= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV100011464; called by muse, mutect2, varscan2
- PDGFRB | c.2340C>A p.P780= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as COSV99940537; called by muse, mutect2, varscan2
- PDZRN3 | c.2838C>A p.R946= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV55210076, COSV99729233; called by muse, mutect2, varscan2
- PEG3 | c.1734G>A p.L578= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV99688720; called by muse, mutect2, varscan2
- PLVAP | c.456G>A p.K152= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as COSV99391625; called by muse, mutect2, varscan2
- PRAMEF12 | c.921G>T p.S307= | Silent (SNP) | VAF 67/245 reads (27%) | catalogued as COSV100743238; called by muse, mutect2, varscan2
- PRSS55 | c.429T>A p.I143= | Silent (SNP) | VAF 97/214 reads (45%) | catalogued as COSV100153764; called by muse, mutect2, varscan2
- RFX4 | c.198G>A p.E66= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV100774510; called by muse, mutect2, varscan2
- RIMS4 | c.456C>T p.A152= | Silent (SNP) | VAF 90/238 reads (38%) | catalogued as COSV100865117; called by muse, mutect2, varscan2
- SCARA5 | c.1056G>A p.K352= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as COSV100107857; called by muse, mutect2, varscan2
- SCN10A | c.3141C>T p.S1047= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV101479371; called by muse, mutect2, varscan2
- SCN3A | c.4161T>C p.L1387= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV99326780; called by muse, mutect2, varscan2
- SERTM1 | c.216C>A p.S72= | Silent (SNP) | VAF 57/130 reads (44%) | catalogued as COSV100171338; called by muse, mutect2, varscan2
- SIGLEC15 | c.687G>T p.L229= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV67180954; called by muse, mutect2, varscan2
- SIX2 | c.627A>G p.L209= | Silent (SNP) | VAF 69/203 reads (34%) | catalogued as COSV100284178; called by muse, mutect2, varscan2
- SLC20A2 | c.1611G>T p.L537= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as COSV100646055; called by muse, mutect2, varscan2
- SLC39A2 | c.171G>T p.L57= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV100068556; called by muse, mutect2, varscan2
- SLIT2 | c.288A>G p.R96= | Silent (SNP) | VAF 28/151 reads (19%) | catalogued as COSV99883444; called by muse, mutect2, varscan2
- SNTG2 | c.936C>A p.S312= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100422320, COSV100425635; called by muse, mutect2, varscan2
- SPAG7 | c.465G>T p.V155= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV99236436; called by muse, mutect2, varscan2
- SRCAP | c.3303G>T p.T1101= | Silent (SNP) | VAF 68/164 reads (41%) | catalogued as rs146926872, COSV99350035; called by muse, mutect2, varscan2
- SSH1 | c.306G>A p.A102= | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as rs372563037; called by muse, mutect2
- ST6GALNAC5 | c.456C>A p.I152= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV100602670, COSV59563253; called by muse, mutect2, varscan2
- STYXL2 | c.2304C>A p.V768= | Silent (SNP) | VAF 67/100 reads (67%) | catalogued as rs145856876, COSV54809895; called by muse, mutect2, varscan2
- SUCLG1 | c.597G>T p.V199= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV101205403; called by muse, mutect2, varscan2
- SUPT16H | c.2910A>G p.A970= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as COSV99250953; called by muse, mutect2, varscan2
- SYCP2 | c.519A>T p.I173= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs774859110, COSV100698217, COSV62765945; called by muse, mutect2, varscan2
- TBC1D14 | c.1845G>T p.L615= | Silent (SNP) | VAF 80/182 reads (44%) | catalogued as COSV68985504; called by muse, mutect2, varscan2
- TGFB3 | c.459C>G p.V153= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99472500, COSV99472503; called by muse, mutect2, varscan2
- TH | c.190C>A p.R64= (on ENST00000381178 / NM_199292.3; = p.R33= on NM_000360.4) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100147088, COSV100147161; called by muse, mutect2
- TMEM132D | c.1839C>T p.F613= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV101242796; called by muse, mutect2, varscan2
- TNK2 | c.3012G>C p.R1004= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100361266; called by muse, mutect2, varscan2
- TRBV27 | c.63C>A p.A21= | Silent (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- TYR | c.9G>A p.L3= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV99634052; called by muse, mutect2, varscan2
- VN1R4 | c.294C>A p.T98= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100237411; called by mutect2, varscan2
- WRN | c.1989G>T p.T663= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs201982706, COSV53300489, COSV99988939; called by muse, mutect2, varscan2
- YME1L1 | c.696G>T p.A232= (on ENST00000326799 / NM_139312.3; = p.A175= on NM_014263.4) | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100463606, COSV58758355; called by muse, mutect2, varscan2
- ZBTB14 | c.225C>T p.V75= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV100813450; called by muse, mutect2, varscan2
- ZNF256 | c.1686C>T p.L562= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs368400089; called by muse, mutect2, varscan2
- ZNF783 | c.138G>T p.V46= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100954235; called by muse, mutect2, varscan2
- ZNF787 | c.960G>C p.V320= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1274192721, COSV99555517; called by muse, mutect2
- ZNF804A | c.2754C>T p.V918= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV100167630; called by muse, mutect2, varscan2
- ZSCAN4 | c.585C>A p.G195= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV99989961; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14750C>A | Intron (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100230308; called by muse, mutect2, varscan2
- EVL | c.352+12060del | Intron (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- GRIA4 | c.2295-5952C>G | Intron (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99231133; called by muse, mutect2, varscan2
- IGKV1-13 | n.139G>T | RNA (SNP) | VAF 46/161 reads (29%) | called by muse, mutect2, varscan2
- MRPL43 | c.466-239G>A | Intron (SNP) | VAF 36/98 reads (37%) | catalogued as rs141726768; called by muse, mutect2, varscan2
- P3H1 | c.2056-103G>T | Intron (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99355165; called by muse, mutect2, varscan2
- SREBF1 | c.92-3048G>T | Intron (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99888774; called by muse, mutect2, varscan2
- SSPOP | n.14007G>T | RNA (SNP) | VAF 20/59 reads (34%) | catalogued as rs913035003, COSV100947327; called by muse, mutect2, varscan2
- UBTFL2 | n.947C>G | RNA (SNP) | VAF 12/27 reads (44%) | called by mutect2, varscan2
